Gene-level copy-number profile of tumor specimen TARGET-40-PAUUML-01A from TARGET case TARGET-40-PAUUML, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 6.0 years (2,177 days).
Specimen TARGET-40-PAUUML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.f26c2e4a-792e-5c79-9e33-078e59084343.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUUML-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 452 have no estimate.
https://portal.gdc.cancer.gov/files/0f1492c5-3912-4c6e-9278-e1ff7f4fe2fe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,900; copy number 2: 14,710; copy number 3: 21,003; copy number 4: 12,378; copy number 5: 3,520; copy number 6: 3,053; copy number 7: 733; copy number 8: 379; copy number 9: 218; copy number 10: 30; copy number 11: 172; copy number 12: 34; copy number 13: 19; copy number 15: 5; copy number 16: 4; copy number 18: 4.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr10:53,766,400–53,766,614, 1 gene: AL365496.1.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr13:68,693,804–68,694,081, 1 gene: RN7SL761P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,598 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:14,124,233–14,304,445, 2 genes, copy number 7–9: RNU6-1265P, AL357873.1.
- chr1:149,782,671–152,516,008, 151 genes, copy number 9–11 (broad region; genes not listed).
- chr1:152,622,834–153,785,821, 81 genes, copy number 9 (broad region; genes not listed).
- chr1:153,793,947–153,802,091, 1 gene, copy number 9: AL513523.2.
- chr1:154,155,304–156,082,465, 113 genes, copy number 8–10 (broad region; genes not listed).
- chr1:170,532,131–173,064,015, 53 genes, copy number 7–9 (within-gene range 4–9): GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1.
- chr1:178,651,706–178,726,285, 3 genes, copy number 15: AL137796.1, MIR4424, AL449106.1.
- chr1:188,869,474–193,060,080, 40 genes, copy number 8–18 (within-gene range 6–18): AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B.
- chr1:194,488,103–194,719,236, 2 genes, copy number 7–8: RNU6-983P, AL353072.1.
- chr1:197,437,976–197,447,469, 1 gene, copy number 8: AL136322.1.
- chr2:99,545,419–104,532,747, 77 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:169,479,480–170,813,670, 30 genes, copy number 7 (within-gene range 6–7): BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2.
- chr2:172,323,260–172,736,206, 11 genes, copy number 7: AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2.
- chr4:30,718,805–32,228,543, 9 genes, copy number 7: AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1.
- chr4:37,073,681–38,139,175, 16 genes, copy number 7 (within-gene range 6–7): AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2.
- chr4:40,316,485–42,892,618, 47 genes, copy number 7: LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802, AC131953.2, NSUN7, ARL4AP2, APBB2, AC131953.1, Y_RNA, RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82.
- chr4:45,995,119–48,426,201, 31 genes, copy number 7 (within-gene range 3–7): RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2.
- chr4:51,843,000–61,153,962, 146 genes, copy number 7–9 (broad region; genes not listed).
- chr4:72,280,969–72,569,221, 2 genes, copy number 8 (within-gene range 2–8): ADAMTS3, AC095056.1.
- chr4:82,610,974–84,299,189, 33 genes, copy number 7: LINC00575, AC067942.4, SCD5, AC073413.1, MIR575, AC073413.2, SEC31A, THAP9-AS1, THAP9, LIN54, Y_RNA, RNU6-615P, COPS4, AC073840.1, PLAC8, AC114781.2, AC114781.3, AC114781.1, COQ2, HPSE, AC114781.5, AC114781.4, HELQ, MRPS18C, ABRAXAS1, SLC25A14P1, RPL30P5, GPAT3, Y_RNA, AC021192.1, AC079160.1, RNU6-774P, AC025538.1.
- chr4:85,100,496–85,246,912, 2 genes, copy number 8: RN7SKP48, AC097488.1.
- chr4:89,836,408–91,904,335, 12 genes, copy number 8–15: SNCA-AS1, MMRN1, AC105445.1, CCSER1, RN7SKP248, AC093729.1, TMSB4XP8, AC004054.1, AC074124.1, AC110774.1, KRT19P6, AC093810.1.
- chr4:94,207,611–96,152,403, 14 genes, copy number 7–9: SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B, UNC5C, AC106881.1, RPL30P6, PDHA2, RNU6-1059P, RNU6-34P.
- chr4:98,928,897–99,352,760, 16 genes, copy number 7 (within-gene range 2–8): AC019131.1, FAM177A1P1, AC019131.3, RNU7-149P, NDUFS5P4, METAP1, MIR3684, ABT1P1, AC019131.2, ADH5, AP002026.1, ADH4, PCNAP1, ADH6, ADH1A, ADH1B.
- chr4:122,378,966–122,732,482, 6 genes, copy number 8: ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P.
- chr4:146,934,001–147,009,145, 3 genes, copy number 7: AC092435.2, AC092435.1, AC092435.3.
- chr8:108,378,831–114,791,929, 49 genes, copy number 7: RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2.
- chr8:123,680,794–124,728,473, 22 genes, copy number 7 (within-gene range 4–7): ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1.
- chr8:126,671,522–129,683,770, 34 genes, copy number 11–12 (within-gene range 4–12): RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr13:25,168,969–25,366,155, 9 genes, copy number 9–12 (within-gene range 2–12): LINC01053, LINC00463, AL359757.1, LINC01076, RPL23AP69, MTMR6, AL590787.1, NUP58, ELOBP1.
- chr14:68,421,698–69,804,331, 37 genes, copy number 7: PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1, DCAF5, DDX18P1, Y_RNA, AL391262.1, AL359317.2, EXD2, AL359317.1, GALNT16, AL157996.1, ERH, SLC39A9, AL157996.2, PLEKHD1, AL133445.1, CCDC177, AL133445.3, SUSD6, AL133445.2, SRSF5, SLC10A1, AL157789.1.
- chr14:105,785,505–106,360,324, 101 genes, copy number 8 (broad region; genes not listed).
- chr17:18,108,706–18,944,073, 53 genes, copy number 9 (within-gene range 6–9): MYO15A, AC087164.1, ALKBH5, LLGL1, FLII, MIEF2, AC127537.1, TOP3A, RPL7AP65, RPL21P121, SMCR8, SHMT1, MIR6778, EVPLL, AL353997.2, AL353997.3, AL353997.5, TBC1D3P4, LINC02076, KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2, CCDC144B, AC107983.1, Metazoa_SRP, TBC1D28, AC026271.2, AC026271.4, AC026271.1, ZNF286B, FOXO3B, UBE2SP2, TRIM16L, AC026271.3, FBXW10, TVP23B, AC107982.3, AC107982.1, PRPSAP2, RN7SL627P, AC107982.2, AC090286.3, AC090286.2.
- chr17:18,951,625–18,954,149, 1 gene, copy number 9: AC090286.1.
- chr17:22,221,221–22,706,703, 27 genes, copy number 8: FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr17:58,660,424–58,692,018, 1 gene, copy number 7 (within-gene range 3–7): IGBP1P2.
- chr17:58,675,286–58,747,340, 5 genes, copy number 7: AC011195.1, RNU1-52P, RNVU1-34, RAD51C, AC025521.1.
- chr17:59,841,266–73,092,712, 328 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr17:74,670,077–75,079,549, 24 genes, copy number 7: AC064805.2, RAB37, CD300LF, AC016888.1, MIR3615, SLC9A3R1, NAT9, TMEM104, GRIN2C, FDXR, FADS6, USH1G, OTOP2, OTOP3, HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P.
- chr17:75,089,862–75,089,974, 1 gene, copy number 7: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 2,213. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
